Somatic mutation profile of tumor specimen C3N-01880-04 (aliquot CPT0244510006) from CPTAC case C3N-01880, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.3 years (24,932 days).
Specimen C3N-01880-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ece7f9a8-d0c1-43e7-a65d-ceb7d0d25de6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01880-31 (Blood Derived Normal), aliquot CPT0244560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f97b0fc9-d1fa-4c5e-aac4-609eed0707b3

The open-access MAF lists 229 somatic variants for this specimen: 164 protein-altering or splice-affecting, 43 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 43, Frame Shift Del 22, Frame Shift Ins 11, Intron 10, 5'UTR 5, Splice Region 4, Nonsense Mutation 4, In Frame Del 4, RNA 3, 3'UTR 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 115/503 reads (23%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3203dup p.N1068Kfs*5 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | catalogued as rs587776802; ClinVar: pathogenic; called by mutect2, pindel
- ABCB10 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747878521, COSV60621846; called by muse, mutect2, varscan2
- ADRA2C | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs748739272; called by muse, mutect2
- ARSL | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 31/562 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs779945606, COSV66965257; called by muse, mutect2
- B3GAT2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57770292; called by muse, mutect2, varscan2
- BAIAP2L1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs771874091; called by muse, mutect2, varscan2
- BMP7 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs776230892, COSV67782177; called by muse, mutect2, varscan2
- BMP8B | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 125/782 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs775864111, COSV59593603; called by muse, mutect2, varscan2
- BORCS6 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 106/423 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs762597553; called by muse, mutect2, varscan2
- CACNA2D3 | c.2185G>C p.G729R | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1395948016, COSV55552740; called by muse, mutect2, varscan2
- CARS2 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.139); catalogued as COSV57287297; called by muse, mutect2, varscan2
- CGB7 | c.400del p.R134Afs*? | Frame Shift Del (DEL) | VAF 48/289 reads (17%) | catalogued as rs755618584; called by mutect2, pindel, varscan2
- CHST12 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 14/441 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393551872; called by muse, mutect2
- CHST13 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV100081186; called by muse, mutect2, varscan2
- COLGALT2 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs753095995; called by muse, mutect2
- CTCF | c.2070del p.E691Sfs*30 | Frame Shift Del (DEL) | VAF 37/166 reads (22%) | catalogued as rs1400980130; called by mutect2, pindel, varscan2
- DCHS2 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 122/445 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.051); catalogued as rs1236455201; called by muse, mutect2, varscan2
- DDX10 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238299167; called by muse, mutect2, varscan2
- DEFB134 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.185); catalogued as rs1283317682, COSV66363066; called by muse, mutect2
- DNAH14 | c.290A>G p.Q97R | Missense Mutation (SNP) | VAF 95/340 reads (28%) | catalogued as rs1443965985; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as rs782552436; called by mutect2, varscan2
- DST | c.16474A>G p.R5492G (on ENST00000361203 / NM_001374722.1; = p.R3080G on NM_015548.5) | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745397027; called by muse, mutect2, varscan2
- ENPP3 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); catalogued as rs535729818, COSV100716507, COSV100717090, COSV62954354; called by muse, mutect2, varscan2
- FBXO2 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 166/459 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs953184967, COSV52354119; called by muse, varscan2
- FMNL3 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53299637; called by muse, mutect2, varscan2
- FOXI2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59094542, COSV99064310; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 36/186 reads (19%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMD4A | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs767134995, COSV62266204; called by muse, mutect2, varscan2
- FRMPD1 | c.4421G>A p.R1474Q | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100899545; called by muse, mutect2
- FUS | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV99568663; called by muse, mutect2
- GPRIN2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782424516; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs754199513; called by mutect2, varscan2
- H1-1 | c.513dup p.P172Tfs*11 | Frame Shift Ins (INS) | VAF 76/299 reads (25%) | catalogued as rs749012967; called by mutect2, varscan2
- HECW2 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as rs775414332, COSV53652950; called by muse, mutect2
- KRTAP13-1 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 115/475 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV62663184; called by muse, mutect2, varscan2
- L3MBTL2 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779700504; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | catalogued as rs780042765; called by mutect2, varscan2
- LMF2 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 98/399 reads (25%) | catalogued as rs771887975, COSV99327600; called by muse, mutect2, varscan2
- LMTK3 | c.3586del p.D1196Tfs*120 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV54316473; called by mutect2, pindel, varscan2
- LRRC3C | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs774102986; called by muse, mutect2, varscan2
- LRRC4C | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375987229; called by muse, mutect2, varscan2
- LY75 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs758257235; called by muse, mutect2, varscan2
- LZTS1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs754615238; called by muse, mutect2, varscan2
- MAN2B2 | c.2897G>A p.R966H | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765499960, COSV53458065; called by muse, mutect2, varscan2
- MEGF8 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs755408868, COSV52093108; called by muse, mutect2, varscan2
- MFNG | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1174070746; called by muse, mutect2, varscan2
- MFSD5 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs761996974; called by muse, mutect2, varscan2
- MID2 | c.1943C>A p.P648H | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV53311497; called by muse, mutect2
- MLXIPL | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 107/344 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1438485905; called by muse, mutect2, varscan2
- MUC12 | c.743T>G p.F248C (on ENST00000379442; = p.F105C on NM_001164462.1) | Missense Mutation (SNP) | VAF 154/527 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.522); catalogued as COSV65190560; called by muse, mutect2, varscan2
- MUC12 | c.15931G>T p.G5311* (on ENST00000379442; = p.G5168* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 13/233 reads (6%) | catalogued as rs367905495; called by muse, mutect2
- NDUFAF7 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 28/663 reads (4%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs1479743929; called by muse, mutect2
- NPY | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 29/532 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs763930002, COSV54214818; called by muse, mutect2
- PAN2 | c.2641C>T p.R881C (on ENST00000425394 / NM_001127460.3; = p.R877C on NM_014871.5) | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771700718; called by muse, mutect2, varscan2
- PCSK5 | c.5348C>T p.A1783V | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs868354124; called by muse, mutect2
- PDE3A | c.511dup p.E171Gfs*49 | Frame Shift Ins (INS) | VAF 46/218 reads (21%) | catalogued as rs780389664; called by mutect2, varscan2
- PDPR | c.1325A>T p.Y442F | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV55352364; called by muse, mutect2
- PGRMC1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 115/420 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs11546864, COSV99483581; called by muse, mutect2, varscan2
- PITPNM2 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185977187; called by muse, mutect2, varscan2
- PKP2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 103/351 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV50741306; called by muse, mutect2, varscan2
- PPP1R27 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as rs370018526; called by muse, mutect2
- PREB | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs931726113; called by muse, mutect2, varscan2
- PRKAG1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60294547; called by muse, mutect2, varscan2
- PSMB6 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1250859844, COSV54513136; called by muse, mutect2
- PTEN | c.92A>T p.N31I | Missense Mutation (SNP) | VAF 106/188 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD115951, COSV64294011; called by muse, mutect2, varscan2
- PTPRJ | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV69254430; called by muse, mutect2
- RABGGTA | c.1192del p.L398Cfs*56 | Frame Shift Del (DEL) | VAF 68/246 reads (28%) | catalogued as rs747920468; called by mutect2, varscan2
- RBPJ | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.71); catalogued as rs778887785; called by muse, mutect2, varscan2
- RNF112 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs766025350, COSV71327116; called by muse, mutect2, varscan2
- RTN3 | c.2836A>T p.I946F (on ENST00000377819 / NM_001265589.2; = p.I150F on NM_006054.4) | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100380482; called by muse, mutect2, varscan2
- SARM1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as rs1254087263; called by muse, mutect2
- SCNN1B | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs377601796, COSV56308401; called by muse, mutect2, varscan2
- SH3YL1 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62156957; called by muse, mutect2, varscan2
- SLIT3 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs138524475; called by muse, mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | catalogued as rs745834619; called by mutect2, pindel, varscan2
- SMOC1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 122/497 reads (25%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.91); catalogued as rs769894716, COSV100734633; called by muse, mutect2, varscan2
- SPAM1 | c.395C>G p.T132R | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV56142846; called by muse, mutect2, varscan2
- STK38L | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs769405820, COSV66521141; called by muse, mutect2, varscan2
- TMEM30B | c.273del p.C92Afs*23 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs979697561; called by mutect2, pindel, varscan2
- TSHR | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs1305132938; called by muse, mutect2
- TTC28 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763920308, COSV67413210; called by muse, mutect2
- TTLL12 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 97/356 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764735601, COSV53356355; called by muse, mutect2, varscan2
- UBE2M | c.34_36del p.K12del | In Frame Del (DEL) | VAF 23/176 reads (13%) | catalogued as rs1465938793; called by pindel, varscan2
- ZDBF2 | c.4875G>A p.M1625I | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104428789; called by muse, mutect2, varscan2
- ZNF776 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs751054656, COSV57816575; called by muse, mutect2, varscan2
- ALX4 | c.1016del p.P339Lfs*12 | Frame Shift Del (DEL) | VAF 92/252 reads (37%) | called by mutect2, pindel, varscan2
- AMPD1 | c.132A>G p.K44= | Splice Region (SNP) | VAF 74/332 reads (22%) | called by muse, mutect2, varscan2
- AP2A2 | c.1551-1G>A p.X517_splice | Splice Site (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
- APC | c.4655_4656del p.E1552Gfs*6 | Frame Shift Del (DEL) | VAF 54/272 reads (20%) | called by pindel, varscan2
- APC | c.4778dup p.P1594Afs*38 | Frame Shift Ins (INS) | VAF 112/509 reads (22%) | called by mutect2, pindel, varscan2
- ARMCX5 | c.247dup p.T83Nfs*3 | Frame Shift Ins (INS) | VAF 62/238 reads (26%) | called by mutect2, pindel, varscan2
- ASPM | c.4423T>C p.Y1475H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2B4 | c.216T>G p.D72E | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ATP8B1 | c.1351A>T p.I451F | Missense Mutation (SNP) | VAF 26/501 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- BCLAF1 | c.1295A>T p.E432V | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- BICC1 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CACNA1B | c.3556C>A p.L1186M | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CASKIN2 | c.3385C>A p.P1129T | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CDH17 | c.540dup p.Q181Sfs*23 | Frame Shift Ins (INS) | VAF 32/134 reads (24%) | called by mutect2, pindel, varscan2
- CEP120 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 9/274 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEP192 | c.7427dup p.L2476Ffs*37 | Frame Shift Ins (INS) | VAF 29/133 reads (22%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COPG1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CTCF | c.1095del p.K365Nfs*2 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel
- DDIT4L | c.158C>G p.T53S | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- DDO | c.279A>G p.S93= | Splice Region (SNP) | VAF 64/175 reads (37%) | called by muse, mutect2, varscan2
- DEPDC1 | c.2202del p.V735Ffs*12 (on ENST00000456315 / NM_001114120.3; = p.V451Ffs*12 on NM_017779.6) | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- DMRTA1 | c.171_176del p.A66_A67del | In Frame Del (DEL) | VAF 63/231 reads (27%) | called by mutect2, pindel, varscan2
- DMRTA2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DST | c.2111_2112del p.F704Cfs*6 (on ENST00000361203 / NM_001374722.1; = p.F378Cfs*6 on NM_001723.6) | Frame Shift Del (DEL) | VAF 94/365 reads (26%) | called by mutect2, pindel, varscan2
- EXD1 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FAM171A2 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCN1 | c.725dup p.S243Qfs*4 | Frame Shift Ins (INS) | VAF 34/128 reads (27%) | called by mutect2, pindel, varscan2
- FHOD3 | c.3613C>T p.R1205* (on ENST00000359247 / NM_001281739.3; = p.R1222* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- FLNA | c.7184G>A p.R2395Q (on ENST00000369850 / NM_001110556.2; = p.R2387Q on NM_001456.3) | Missense Mutation (SNP) | VAF 81/310 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- FYB1 | c.972del p.P325Hfs*44 | Frame Shift Del (DEL) | VAF 46/230 reads (20%) | called by mutect2, pindel, varscan2
- GABRA2 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAD2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GRK2 | c.1768_1772del p.W590Gfs*45 | Frame Shift Del (DEL) | VAF 90/321 reads (28%) | called by mutect2, pindel, varscan2
- HOXD11 | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by mutect2, varscan2
- IGHG1 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 89/329 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK2 | c.1111G>A p.G371R (on ENST00000444842 / NM_001017425.3; = p.G356R on NM_014217.4) | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KMT2B | c.5462dup p.L1822Tfs*12 | Frame Shift Ins (INS) | VAF 55/221 reads (25%) | called by mutect2, pindel, varscan2
- LRRC41 | c.77C>A p.T26K | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MAP3K3 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAU2 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 138/452 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- MBD6 | c.2445dup p.E816Rfs*32 | Frame Shift Ins (INS) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- ME3 | c.1050G>T p.M350I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- MEGF11 | c.2857C>A p.L953I | Missense Mutation (SNP) | VAF 89/389 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MEP1A | c.145+1G>A p.X49_splice | Splice Site (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- MLLT6 | c.718_720del p.K240del | In Frame Del (DEL) | VAF 6/35 reads (17%) | called by pindel, varscan2
- MPP5 | c.1969A>T p.R657W | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- NAA10 | c.42G>A p.M14I | Missense Mutation (SNP) | VAF 150/576 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NIBAN1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPAS1 | c.1388del p.I463Tfs*41 | Frame Shift Del (DEL) | VAF 156/678 reads (23%) | called by mutect2, pindel, varscan2
- NPIPA5 | c.743C>G p.P248R | Missense Mutation (SNP) | VAF 82/1453 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2
- OR2Z1 | c.815A>T p.N272I | Missense Mutation (SNP) | VAF 157/577 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- OR52N4 | c.889dup p.V297Gfs*18 | Frame Shift Ins (INS) | VAF 66/272 reads (24%) | called by mutect2, pindel, varscan2
- PARP14 | c.4714A>G p.N1572D | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PARP14 | c.4715A>T p.N1572I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PCSK1N | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 163/469 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PDE4DIP | c.2216G>T p.R739I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- PEAR1 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROCR | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROKR1 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 17/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRPF38A | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PRX | c.3277C>T p.Q1093* | Nonsense Mutation (SNP) | VAF 97/365 reads (27%) | called by muse, mutect2, varscan2
- PTPRT | c.3765C>A p.N1255K | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAB3C | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RPGRIP1 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SLC12A9 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2
- SLC39A4 | c.1762T>A p.W588R (on ENST00000301305 / NM_001374839.1; = p.W563R on NM_017767.3) | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SNX17 | c.681+7T>C | Splice Region (SNP) | VAF 41/130 reads (32%) | called by muse, mutect2, varscan2
- TAS2R4 | c.252del p.F84Lfs*16 | Frame Shift Del (DEL) | VAF 38/172 reads (22%) | called by mutect2, varscan2
- TAT | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 154/491 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- TBL1XR1 | c.627del p.V210Yfs*22 | Frame Shift Del (DEL) | VAF 121/237 reads (51%) | called by mutect2, pindel, varscan2
- TFAP4 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TRIB1 | c.859T>G p.S287A | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.437); called by muse, mutect2
- TTC7A | c.2154T>G p.A718= | Splice Region (SNP) | VAF 29/70 reads (41%) | called by muse, varscan2
- URI1 | c.438_440del p.E146del | In Frame Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- ZNF717 | c.1236A>G p.I412M | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); called by muse, mutect2
- ZNF746 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCA5 | c.3738T>G p.L1246= | Silent (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- AGO3 | c.870C>T p.A290= | Silent (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- ALPL | c.988C>T p.L330= | Silent (SNP) | VAF 9/215 reads (4%) | called by muse, mutect2
- AP2A2 | c.909C>T p.N303= | Silent (SNP) | VAF 14/298 reads (5%) | catalogued as rs758190413, COSV100173197; called by muse, mutect2
- ARID1B | c.3237C>T p.A1079= | Silent (SNP) | VAF 28/458 reads (6%) | catalogued as rs746210543; called by muse, mutect2
- B3GNT2 | c.150G>A p.K50= | Silent (SNP) | VAF 30/129 reads (23%) | called by muse, mutect2, varscan2
- CACNA1E | c.4335G>A p.A1445= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as rs779279181; called by muse, mutect2, varscan2
- CEP89 | c.525C>T p.D175= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs777300690; called by muse, mutect2, varscan2
- CHRNA10 | c.486G>A p.P162= | Silent (SNP) | VAF 92/412 reads (22%) | catalogued as rs1311370606; called by muse, mutect2, varscan2
- CRLF2 | c.624C>T p.C208= | Silent (SNP) | VAF 60/234 reads (26%) | called by muse, mutect2, varscan2
- DAB2 | c.1608A>G p.Q536= | Silent (SNP) | VAF 16/312 reads (5%) | catalogued as COSV100297862; called by muse, mutect2
- DCLK1 | c.453G>A p.S151= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs775336522, COSV55190963; called by muse, mutect2
- DNAJC25 | c.726T>C p.C242= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs1424820435; called by muse, mutect2, varscan2
- EIF4H | c.303C>T p.Y101= | Silent (SNP) | VAF 47/180 reads (26%) | catalogued as rs782820960, COSV56083582; called by muse, mutect2, varscan2
- FAM149B1 | c.1293G>A p.T431= | Silent (SNP) | VAF 88/333 reads (26%) | catalogued as rs748791406; called by muse, mutect2, varscan2
- FBXL7 | c.969C>T p.C323= | Silent (SNP) | VAF 10/258 reads (4%) | catalogued as COSV61651768; called by muse, mutect2
- FLNA | c.1407C>T p.P469= | Silent (SNP) | VAF 49/138 reads (36%) | called by muse, mutect2, varscan2
- FN1 | c.2799A>G p.A933= | Silent (SNP) | VAF 124/436 reads (28%) | called by muse, mutect2, varscan2
- GGT1 | c.72C>G p.L24= | Silent (SNP) | VAF 115/447 reads (26%) | called by muse, mutect2, varscan2
- GYS1 | c.1179C>T p.A393= | Silent (SNP) | VAF 145/583 reads (25%) | called by muse, mutect2, varscan2
- KBTBD8 | c.1056C>T p.I352= | Silent (SNP) | VAF 80/291 reads (27%) | catalogued as rs148413681; called by muse, mutect2, varscan2
- LMX1B | c.301C>T p.L101= | Silent (SNP) | VAF 66/299 reads (22%) | called by muse, mutect2, varscan2
- NBEA | c.4623T>C p.V1541= | Silent (SNP) | VAF 56/238 reads (24%) | called by muse, mutect2, varscan2
- OPLAH | c.3750C>T p.G1250= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2
- PAK5 | c.1260C>T p.S420= | Silent (SNP) | VAF 49/165 reads (30%) | catalogued as rs367976201, COSV62022631; called by muse, mutect2, varscan2
- PARP4 | c.3930A>G p.T1310= | Silent (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1056C>T p.G352= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as rs749506672, COSV59997340; called by muse, mutect2, varscan2
- PLSCR3 | c.466C>T p.L156= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs1312325199; called by muse, mutect2, varscan2
- PNPLA7 | c.2992C>T p.L998= | Silent (SNP) | VAF 110/401 reads (27%) | called by muse, mutect2, varscan2
- PPP1R3A | c.2721T>C p.N907= | Silent (SNP) | VAF 64/239 reads (27%) | catalogued as rs752480533, COSV52889094; called by muse, mutect2, varscan2
- RNF40 | c.1321C>T p.L441= | Silent (SNP) | VAF 21/271 reads (8%) | called by muse, mutect2
- SEC16A | c.2211C>T p.N737= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs762230036; called by muse, mutect2, varscan2
- SHH | c.771G>A p.T257= | Silent (SNP) | VAF 23/507 reads (5%) | called by muse, mutect2
- SLC14A2 | c.1182C>T p.G394= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs150647679; called by muse, mutect2
- SLC35F5 | c.582G>A p.V194= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs768213121; called by muse, mutect2, varscan2
- SLC6A9 | c.702C>T p.D234= (on ENST00000360584 / NM_201649.4; = p.D180= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 105/635 reads (17%) | catalogued as rs929225398; called by muse, mutect2, varscan2
- TAOK3 | c.649C>A p.R217= | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as COSV66828538; called by muse, mutect2, varscan2
- TBC1D9 | c.3363C>T p.S1121= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs537809337; called by muse, mutect2, varscan2
- TOP2A | c.2841C>T p.T947= | Silent (SNP) | VAF 81/334 reads (24%) | catalogued as rs373156274; called by muse, mutect2, varscan2
- UBQLN1 | c.528G>A p.Q176= | Silent (SNP) | VAF 9/241 reads (4%) | catalogued as COSV57409725; called by muse, mutect2
- UNC13A | c.1710C>T p.C570= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as rs957406997, COSV53193465; called by muse, mutect2, varscan2
- WHRN | c.384C>T p.G128= | Silent (SNP) | VAF 11/299 reads (4%) | called by muse, mutect2
- ZNF324B | c.1092G>A p.A364= | Silent (SNP) | VAF 63/239 reads (26%) | catalogued as rs769075987; called by muse, mutect2, varscan2
- AC064807.1 | n.837del | RNA (DEL) | VAF 59/246 reads (24%) | catalogued as rs967669999; called by mutect2, pindel, varscan2
- AC107023.1 | n.25+3030G>A | Intron (SNP) | VAF 45/168 reads (27%) | called by muse, mutect2, varscan2
- AC241585.2 | n.601del | RNA (DEL) | VAF 30/172 reads (17%) | called by mutect2, varscan2
- AP000769.3 | chr11:65505159 C>T | 5'Flank (SNP) | VAF 30/136 reads (22%) | catalogued as rs780525347; called by muse, mutect2, varscan2
- ASL | c.656-3del | Intron (DEL) | VAF 116/418 reads (28%) | catalogued as rs778811159; called by mutect2, varscan2
- CFHR3 | c.613+434G>A | Intron (SNP) | VAF 48/201 reads (24%) | catalogued as rs773818679; called by muse, mutect2, varscan2
- CHRNA2 | c.*14G>A | 3'UTR (SNP) | VAF 46/142 reads (32%) | catalogued as rs779112876; called by muse, mutect2, varscan2
- CHST5 | c.-1221T>G | 5'UTR (SNP) | VAF 78/280 reads (28%) | called by muse, mutect2, varscan2
- CLUH | c.2974+17G>T | Intron (SNP) | VAF 102/285 reads (36%) | called by muse, mutect2, varscan2
- CYP2C8 | c.1150-46T>C | Intron (SNP) | VAF 61/213 reads (29%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.703+111G>T | Intron (SNP) | VAF 105/366 reads (29%) | called by muse, mutect2, varscan2
- EXOC4 | c.1417+3920C>T | Intron (SNP) | VAF 56/169 reads (33%) | called by muse, mutect2, varscan2
- IFI30 | c.*4C>T | 3'UTR (SNP) | VAF 11/363 reads (3%) | called by muse, mutect2
- IRF4 | c.-22G>A | 5'UTR (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2
- MIR7-2 | n.41A>G | RNA (SNP) | VAF 48/235 reads (20%) | called by muse, mutect2, varscan2
- MTRR | c.1638+42C>T | Intron (SNP) | VAF 33/168 reads (20%) | catalogued as rs1424191987; called by muse, mutect2, varscan2
- PDCD6 | c.-12G>T | 5'UTR (SNP) | VAF 85/375 reads (23%) | called by muse, mutect2, varscan2
- PLP1 | c.453+55C>T | Intron (SNP) | VAF 21/72 reads (29%) | catalogued as rs762333078; called by muse, mutect2, varscan2
- RELN | c.-29C>T | 5'UTR (SNP) | VAF 34/65 reads (52%) | catalogued as rs779534888; ClinVar: uncertain significance; called by muse, varscan2
- SLC31A2 | c.-36C>T | 5'UTR (SNP) | VAF 7/15 reads (47%) | catalogued as rs1314035297; called by muse, mutect2, varscan2
- STAC3 | c.*158G>A | 3'UTR (SNP) | VAF 10/270 reads (4%) | catalogued as rs1350956210; called by muse, mutect2
- THAP2 | c.71+382G>A | Intron (SNP) | VAF 64/205 reads (31%) | called by muse, mutect2, varscan2
